Somatic mutation profile of tumor specimen TCGA-98-A539-01A (aliquot TCGA-98-A539-01A-31D-A25L-08) from TCGA case TCGA-98-A539, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.2 years (23,098 days).
Specimen TCGA-98-A539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58f6ea96-7838-4e18-a73c-7aae67b6e673.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-A539-10A (Blood Derived Normal), aliquot TCGA-98-A539-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c443eeaa-f061-434b-88df-3793d87e580c

The open-access MAF lists 191 somatic variants for this specimen: 148 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 39, Nonsense Mutation 9, Splice Site 6, Frame Shift Del 5, RNA 2, Nonstop Mutation 1, In Frame Del 1, Intron 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV50260372, COSV50272556, COSV50274400; called by muse, mutect2, varscan2
- ALG8 | c.413C>G p.T138R | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.195); catalogued as CD033525, COSV100219970; called by muse, mutect2, varscan2
- ANKRD34B | c.776A>T p.N259I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV100103370; called by muse, mutect2, varscan2
- ANKZF1 | c.1485G>C p.W495C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs758245062, COSV55477550, COSV99850242; called by muse, mutect2, varscan2
- ARAP1 | c.4174C>G p.L1392V (on ENST00000393609 / NM_001040118.2; = p.L1147V on NM_015242.4) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV100501553; called by muse, mutect2, varscan2
- ARNTL2 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV99667520; called by muse, mutect2, varscan2
- BAP1 | c.296T>A p.V99E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99963421; called by muse, mutect2, varscan2
- BIN2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs763853539, COSV99909175; called by muse, mutect2, varscan2
- CADPS | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99335937; called by muse, mutect2, varscan2
- CALCOCO1 | c.1806G>T p.E602D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); catalogued as COSV100017161; called by muse, mutect2, varscan2
- CBX6 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1409035761, COSV99327966; called by muse, mutect2, varscan2
- CCDC85A | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV101339375; called by muse, mutect2
- CFAP46 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100886260; called by muse, mutect2, varscan2
- CFH | c.2542G>T p.G848* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100808824, COSV66410482; called by muse, mutect2, varscan2
- CHGA | c.1181G>A p.W394* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV50894033; called by muse, mutect2, varscan2
- CHRM2 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100280750; called by muse, mutect2, varscan2
- CKAP5 | c.1987C>T p.H663Y | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs1389310316, COSV100370393; called by muse, mutect2, varscan2
- COBLL1 | c.1198C>T p.R400* (on ENST00000392717; = p.R362* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 24/177 reads (14%) | catalogued as rs769963140, COSV52065792; called by muse, mutect2, varscan2
- COL5A2 | c.2911C>A p.P971T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100880013; called by muse, mutect2, varscan2
- COL6A3 | c.200A>T p.K67I | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV99796212; called by muse, mutect2, varscan2
- COMT | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1377127608, COSV99258292; called by muse, mutect2, varscan2
- CPZ | c.1829T>C p.L610S (on ENST00000360986 / NM_001014447.3; = p.L599S on NM_003652.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV59923675; called by muse, mutect2, varscan2
- DAB1 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV100139473; called by muse, mutect2, varscan2
- DHX29 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.849); catalogued as COSV99286969; called by muse, mutect2, varscan2
- DNAI1 | c.1403G>C p.R468T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99646577; called by muse, mutect2, varscan2
- EMB | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296610; called by muse, mutect2, varscan2
- ETV5 | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100112046; called by muse, mutect2
- EXOC3L1 | c.1836C>A p.D612E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99333425; called by muse, mutect2, varscan2
- EXTL2 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100921082; called by muse, mutect2, varscan2
- FAM120B | c.1954G>T p.V652L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99378950; called by muse, mutect2, varscan2
- FAN1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 33/185 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100755819, COSV62949645; called by muse, mutect2, varscan2
- FBF1 | c.2233G>A p.E745K (on ENST00000586717; = p.E759K on NM_001319193.1) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs750132953, COSV100044744; called by muse, mutect2, varscan2
- FPR2 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.506); catalogued as rs1210873063, COSV100389118; called by muse, mutect2
- FRAS1 | c.8234G>T p.G2745V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV53637587, COSV99348287; called by muse, mutect2, varscan2
- GALNT13 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101222220, COSV67215652; called by muse, mutect2, varscan2
- GCN1 | c.3741T>G p.Y1247* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100324662; called by muse, mutect2, varscan2
- GPR149 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101078113, COSV101078170; called by muse, mutect2, varscan2
- GPR32 | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); catalogued as COSV54514308, COSV99567074; called by muse, mutect2, varscan2
- GRIA3 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV52084359, COSV99988996; called by muse, mutect2, varscan2
- GRK7 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as COSV99379512; called by muse, mutect2, varscan2
- HAPLN4 | c.803C>A p.T268K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99363612; called by muse, mutect2, varscan2
- HEATR1 | c.4189C>T p.P1397S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs759055188, COSV100857433; called by muse, mutect2, varscan2
- HERC1 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.376); catalogued as COSV101496332; called by muse, mutect2, varscan2
- IL1RL2 | c.955G>C p.G319R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99960229; called by muse, mutect2, varscan2
- IL1RL2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99960231; called by muse, mutect2, varscan2
- IL7R | c.1378T>A p.*460Rext*7 | Nonstop Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100285913; called by muse, mutect2, varscan2
- IRF2BPL | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as COSV99467744; called by muse, mutect2, varscan2
- KCNJ6 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV99899128; called by muse, mutect2
- KIAA0586 | c.2677G>T p.G893C (on ENST00000619416 / NM_001244190.2; = p.G832C on NM_014749.5) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707514; called by muse, mutect2, varscan2
- KIF22 | c.1951-1G>A p.X651_splice | Splice Site (SNP) | VAF 10/184 reads (5%) | catalogued as COSV99360846; called by muse, mutect2
- KIF5A | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54058927, COSV99672449; called by muse, mutect2, varscan2
- KIT | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55419883, COSV99853300; called by muse, mutect2, varscan2
- KLHL4 | c.591G>T p.R197S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100909128; called by muse, mutect2, varscan2
- KLRF1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99684294; called by muse, mutect2, varscan2
- KMT2C | c.12694G>C p.E4232Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV100066945; called by muse, mutect2, varscan2
- KRT6B | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV99360461; called by muse, mutect2, varscan2
- LAMA2 | c.4118C>T p.P1373L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs754163400, COSV101370046; called by muse, mutect2, varscan2
- LRP1B | c.12779G>A p.G4260E | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1208377840, COSV67244466; called by muse, mutect2, varscan2
- LRRK2 | c.3097-1G>T p.X1033_splice | Splice Site (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100109256, COSV104406140; called by muse, mutect2
- MEGF10 | c.917+1G>T p.X306_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99078959, COSV99174714; called by muse, mutect2, varscan2
- MGAT5B | c.2121C>A p.H707Q (on ENST00000569840 / NM_001199172.2; = p.H705Q on NM_144677.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.437); catalogued as COSV100047269; called by muse, mutect2, varscan2
- MNDA | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as COSV100933243; called by muse, mutect2
- MNDA | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs372443942, COSV63741572; called by muse, mutect2
- MNS1 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV99549373; called by muse, mutect2, varscan2
- MTA1 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100494924; called by muse, mutect2, varscan2
- MTMR4 | c.2440del p.V814Ffs*13 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | catalogued as COSV60202823; called by mutect2, pindel, varscan2
- MUC17 | c.8857G>T p.V2953F | Missense Mutation (SNP) | VAF 97/401 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV100071616; called by muse, mutect2, varscan2
- NCAM2 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99521278; called by muse, mutect2, varscan2
- NCEH1 | c.350C>G p.T117R (on ENST00000538775; = p.T85R on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV99859818; called by muse, mutect2, varscan2
- NCOA1 | c.1145C>A p.S382* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99945202; called by muse, mutect2, varscan2
- NECTIN1 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99871778; called by muse, mutect2, varscan2
- NOS1 | c.3854T>A p.V1285D | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100500037; called by muse, mutect2, varscan2
- NOTCH4 | c.5974G>A p.E1992K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs772730975, COSV100900361, COSV66679451; called by muse, mutect2, varscan2
- NOX1 | c.1411C>A p.R471S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV99471415; called by muse, mutect2, varscan2
- NR5A2 | c.646A>T p.I216F (on ENST00000367362 / NM_205860.3; = p.I170F on NM_003822.5) | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.573); catalogued as COSV99370662; called by muse, mutect2, varscan2
- NRXN3 | c.2956C>A p.L986M (on ENST00000335750 / NM_001330195.2; = p.L613M on NM_004796.6) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100200789; called by muse, mutect2, varscan2
- NTRK2 | c.1690C>T p.Q564* (on ENST00000323115 / NM_001369534.1; = p.Q580* on NM_006180.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99452415; called by muse, mutect2, varscan2
- OR10G3 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370362611; called by muse, mutect2, varscan2
- OR10X1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV100936589, COSV63768208; called by muse, mutect2
- OR2B3 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV101013748; called by muse, mutect2, varscan2
- OR2T34 | c.682C>A p.H228N | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV100170228; called by muse, mutect2, varscan2
- OR52B4 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV101281571, COSV101281585; called by muse, varscan2
- OR52B4 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101281572; called by muse, varscan2
- OR5D14 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs866360109, COSV100162124; called by muse, mutect2, varscan2
- OR8D1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100766533, COSV63441923; called by muse, mutect2, varscan2
- OR8K3 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV100449656, COSV57130786; called by muse, mutect2, varscan2
- PAK3 | c.835C>G p.P279A (on ENST00000262836 / NM_001324328.2; = p.P264A on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99456548; called by muse, mutect2, varscan2
- PAPPA | c.1919A>T p.D640V | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100072878; called by muse, mutect2, varscan2
- PAPPA | c.3865G>C p.D1289H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100072881; called by muse, mutect2, varscan2
- PASK | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV99298451, COSV99298652; called by muse, mutect2, varscan2
- PCDHA12 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV56515332; called by muse, mutect2, varscan2
- PCDHGB4 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.718); catalogued as COSV99530782; called by muse, mutect2, varscan2
- PDZD2 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223716; called by muse, mutect2, varscan2
- PHRF1 | c.2648C>G p.T883R (on ENST00000264555 / NM_001286581.2; = p.T882R on NM_020901.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99199477; called by muse, mutect2, varscan2
- PKHD1L1 | c.4867A>C p.N1623H | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV101005392; called by muse, mutect2
- PNN | c.499-1G>T p.X167_splice | Splice Site (SNP) | VAF 30/93 reads (32%) | catalogued as COSV99397043; called by muse, mutect2, varscan2
- POM121L12 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as COSV101374842; called by muse, mutect2, varscan2
- PRICKLE2 | c.2434G>A p.A812T (on ENST00000295902; = p.A756T on NM_198859.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.175); catalogued as COSV99896638; called by muse, mutect2, varscan2
- PRKCH | c.1376A>T p.Y459F | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100272796; called by muse, mutect2, varscan2
- PTGER3 | c.1013A>C p.N338T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100138240; called by muse, mutect2, varscan2
- RADIL | c.1628C>A p.S543* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV101271267; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RSBN1L | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100615888; called by muse, mutect2
- SCN10A | c.5352A>G p.I1784M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV71861687; called by muse, mutect2, varscan2
- SHMT1 | c.684C>G p.D228E | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363460; called by muse, mutect2, varscan2
- SIGLEC5 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV99706947; called by muse, mutect2, varscan2
- SLC22A1 | c.1514T>G p.L505R | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100266402; called by muse, mutect2
- SLC27A6 | c.1313C>G p.A438G | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99322146; called by muse, mutect2, varscan2
- SLC2A13 | c.1438T>A p.W480R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.265); catalogued as COSV99785930; called by muse, mutect2, varscan2
- SLC44A5 | c.1739A>G p.Y580C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100901162; called by muse, mutect2
- SLCO1B1 | c.962del p.N321Mfs*2 | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | catalogued as rs1565679515; called by mutect2, pindel, varscan2
- SLFN12 | c.306C>A p.Y102* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100512917; called by muse, mutect2, varscan2
- SLITRK2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV100157328; called by muse, mutect2, varscan2
- SNAPC4 | c.2335C>T p.Q779* | Nonsense Mutation (SNP) | VAF 30/176 reads (17%) | catalogued as COSV100046797; called by muse, mutect2, varscan2
- SRSF12 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as COSV101504959; called by muse, mutect2, varscan2
- SSTR1 | c.482A>G p.H161R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs748436222, COSV99942705; called by muse, mutect2, varscan2
- TEX47 | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99787171, COSV99787234; called by muse, mutect2
- THSD4 | c.1642A>C p.N548H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV99964507; called by muse, mutect2, varscan2
- TLE1 | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100916243; called by muse, mutect2, varscan2
- TMC2 | c.1969G>C p.V657L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.516); catalogued as COSV100727351; called by muse, mutect2, varscan2
- TRIM48 | c.297G>T p.W99C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs767149810, COSV101338191; called by muse, mutect2, varscan2
- TTN | c.93071T>A p.L31024Q (on ENST00000591111; = p.L23600Q on NM_003319.4) | Missense Mutation (SNP) | VAF 42/235 reads (18%) | PolyPhen probably damaging (0.931); catalogued as COSV100594468; called by muse, mutect2, varscan2
- TTN | c.33608C>A p.A11203E (on ENST00000591111; = p.A10276E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | PolyPhen benign (0.001); catalogued as COSV100594470; called by muse, mutect2, varscan2
- TTN | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | PolyPhen possibly damaging (0.49); catalogued as rs138945705; called by muse, mutect2, varscan2
- UCHL5 | c.692A>T p.Y231F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100815274; called by muse, mutect2
- UGT2B10 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV55321575; called by muse, mutect2, varscan2
- USE1 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV99812357; called by muse, varscan2
- VIPR2 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.184); catalogued as COSV100056553, COSV51104375; called by muse, mutect2, varscan2
- VSIG10 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100821248; called by muse, mutect2, varscan2
- WBP11 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs761866849, COSV53763829; called by muse, mutect2, varscan2
- WEE2 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV101187646; called by muse, mutect2, varscan2
- ZBTB16 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV60088768; called by muse, mutect2, varscan2
- ZFHX4 | c.1501C>A p.P501T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV99256294; called by muse, mutect2, varscan2
- ZHX2 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58716421; called by muse, mutect2, varscan2
- ZNF544 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV99516778; called by muse, mutect2, varscan2
- ZNF773 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775678935, COSV99989081; called by muse, mutect2, varscan2
- ZNF804A | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV56476591; called by muse, mutect2, varscan2
- ZNF804A | c.1822A>G p.M608V | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs776017545, COSV100166443; called by muse, mutect2, varscan2
- ZNF99 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV68055553; called by muse, mutect2, varscan2
- ZSCAN9 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV99356308; called by muse, mutect2, varscan2
- CDKN2A | c.371_380del p.R124Hfs*19 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- COL22A1 | c.4141-4_4141-2delinsTTGG p.X1381_splice | Splice Site (INS) | VAF 7/48 reads (15%) | called by pindel, varscan2*
- FAM219A | c.73_75del p.A25del | In Frame Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2
- FBXW7 | c.1235_1236+1del p.X412_splice (on ENST00000281708 / NM_001349798.2; = p.X332_splice on NM_018315.5) | Splice Site (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- IGKV2-24 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- IQCN | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2
- POLQ | c.5357del p.S1786Ifs*30 | Frame Shift Del (DEL) | VAF 31/159 reads (19%) | called by mutect2, pindel, varscan2
- CA7 | c.759G>A p.L253= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100623716; called by muse, mutect2, varscan2
- CBLN1 | c.393C>A p.L131= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99535565; called by muse, mutect2, varscan2
- CHST4 | c.813C>T p.Y271= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100632805; called by muse, mutect2, varscan2
- CLCN6 | c.1137C>T p.L379= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV100411586; called by muse, mutect2, varscan2
- CLDN25 | c.684C>T p.V228= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV101493580; called by muse, mutect2, varscan2
- COMMD10 | c.504T>C p.D168= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99174508; called by muse, mutect2
- CYP2B6 | c.1473C>A p.R491= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100137293; called by muse, mutect2, varscan2
- FRMPD1 | c.2574C>G p.A858= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV100899312; called by muse, mutect2, varscan2
- GALNTL6 | c.897G>A p.Q299= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV101560110; called by muse, mutect2, varscan2
- HMCN1 | c.6127C>T p.L2043= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV99624238; called by muse, mutect2
- HUWE1 | c.4212G>A p.E1404= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99470647; called by muse, mutect2
- IGHD | c.642C>A p.G214= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV101162797; called by muse, mutect2, varscan2
- INSL5 | c.40C>T p.L14= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs759887485, COSV100455376, COSV100455442; called by muse, mutect2, varscan2
- KIRREL3 | c.1386G>T p.S462= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101375168; called by muse, varscan2
- KLHL22 | c.1140C>T p.F380= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100185791; called by muse, mutect2, varscan2
- LAMA5 | c.10752T>C p.D3584= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99438068; called by muse, varscan2
- LAMC2 | c.3561C>A p.T1187= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV99679705; called by muse, mutect2, varscan2
- LIN28B | c.165C>A p.P55= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV100558532; called by muse, mutect2, varscan2
- MATK | c.492C>T p.R164= (on ENST00000310132 / NM_139355.3; = p.R165= on NM_002378.4) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs372033387; called by muse, mutect2, varscan2
- MROH2B | c.2619G>A p.L873= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV101270475; called by muse, mutect2, varscan2
- MYO18B | c.7461G>T p.G2487= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs545198222, COSV100122633, COSV100123382, COSV59133056; called by muse, mutect2, varscan2
- NKX2-2 | c.6G>T p.S2= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1286194758, COSV101010495; called by muse, mutect2
- OR2B11 | c.372G>C p.L124= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100275262, COSV59509341; called by mutect2, varscan2
- OVCH1 | c.2988C>T p.I996= | Silent (SNP) | VAF 44/228 reads (19%) | catalogued as COSV100548235; called by muse, mutect2, varscan2
- PCDHGA1 | c.405A>G p.L135= | Silent (SNP) | VAF 59/208 reads (28%) | catalogued as COSV100965923; called by muse, mutect2, varscan2
- PCLO | c.2121G>A p.V707= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100427325, COSV61644214; called by muse, mutect2, varscan2
- PFKL | c.834C>T p.Y278= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs770086693, COSV62466486; called by muse, mutect2, varscan2
- RFXANK | c.316C>T p.L106= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100284434; called by mutect2, varscan2
- RPAP3 | c.1522C>T p.L508= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV99139267; called by muse, mutect2, varscan2
- SGCZ | c.486G>A p.R162= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs1376386740, COSV66016487; called by muse, mutect2
- SLC1A7 | c.1578C>G p.T526= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100439342; called by muse, mutect2, varscan2
- SYNE1 | c.22944T>A p.A7648= (on ENST00000367255 / NM_182961.4; = p.A7577= on NM_033071.3) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99553577; called by muse, mutect2, varscan2
- TMCC3 | c.855C>G p.G285= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV54154618, COSV99705207; called by muse, mutect2, varscan2
- TNKS2 | c.2592C>T p.S864= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV100860997; called by muse, mutect2, varscan2
- TRIML2 | c.339C>G p.L113= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100455873; called by muse, mutect2
- USP53 | c.801A>C p.A267= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs1190741149, COSV99917510; called by muse, mutect2
- UTY | c.2520A>T p.S840= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV100229367; called by muse, mutect2, varscan2
- ZNF347 | c.336A>G p.V112= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100498125; called by muse, mutect2
- ZNF618 | c.504G>A p.A168= (on ENST00000374126 / NM_001318042.2; = p.A136= on NM_133374.2) | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs200100133; called by muse, mutect2, varscan2
- EPB41L4B | c.1409+1955G>A | Intron (SNP) | VAF 15/172 reads (9%) | catalogued as COSV101000447, COSV65798695; called by muse, mutect2
- OOSP2 | c.-2C>T | 5'UTR (SNP) | VAF 17/121 reads (14%) | catalogued as rs1306785782, COSV99613117; called by muse, mutect2, varscan2
- TUBB7P | n.1227G>A | RNA (SNP) | VAF 16/191 reads (8%) | called by muse, mutect2
- UBTFL2 | n.381G>T | RNA (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
